Somatic mutation profile of tumor specimen MP2PRT-PAUSBG-TMP1-A (aliquot MP2PRT-PAUSBG-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUSBG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,008 days).
Specimen MP2PRT-PAUSBG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c21cc4a5-9a4e-4972-9cc7-84e6f8661f39.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSBG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSBG-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1fc6e1cb-8b78-4eca-aa9f-48ade1086d73

The open-access MAF lists 10 somatic variants for this specimen: 6 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 6, Silent 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MEF2C | c.68A>G p.K23R | Missense Mutation (SNP) | VAF 37/244 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs797045053; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- GPATCH3 | c.937C>A p.Q313K | Missense Mutation (SNP) | VAF 201/567 reads (35%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV100658693; called by muse, mutect2, varscan2
- RYR1 | c.6989G>A p.R2330H | Missense Mutation (SNP) | VAF 72/400 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as rs774118116; called by muse, mutect2, varscan2
- UGT1A4 | c.278C>T p.T93M | Missense Mutation (SNP) | VAF 77/443 reads (17%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs188914242; called by muse, mutect2, varscan2
- FRAS1 | c.3125C>A p.A1042E | Missense Mutation (SNP) | VAF 104/337 reads (31%) | SIFT tolerated (0.21); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- GLUD2 | c.1447G>A p.G483R | Missense Mutation (SNP) | VAF 145/233 reads (62%) | SIFT tolerated (0.06); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- CD68 | c.1053C>T p.Y351= | Silent (SNP) | VAF 122/414 reads (29%) | catalogued as rs1357802548; called by muse, mutect2, varscan2
- IGKV1OR2-108 | chr2:113406872 TC>AGCGGA | Silent (INS) | VAF 54/170 reads (32%) | called by pindel, varscan2*
- NRXN1 | c.291C>T p.C97= | Silent (SNP) | VAF 223/646 reads (35%) | catalogued as rs973639826, COSV68017838; called by muse, varscan2
- SPTAN1 | c.2235A>G p.Q745= | Silent (SNP) | VAF 105/281 reads (37%) | called by muse, mutect2, varscan2
